Somatic mutation profile of tumor specimen MP2PRT-PAVZJJ-TMP1-A (aliquot MP2PRT-PAVZJJ-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVZJJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,250 days).
Specimen MP2PRT-PAVZJJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa0c5931-b930-44cf-bbae-00473618386d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVZJJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVZJJ-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f578f71-5fc3-415d-9e98-1f0e7306ec71

The open-access MAF lists 17 somatic variants for this specimen: 16 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 13, In Frame Del 1, Silent 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.5930C>A p.T1977K | Missense Mutation (SNP) | VAF 23/139 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs587777893, COSV63868784, COSV63869673, COSV63869920; ClinVar: not provided; called by muse, mutect2, varscan2
- CACNA1B | c.6814G>A p.A2272T | Missense Mutation (SNP) | VAF 183/382 reads (48%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs763026357, COSV53119943; called by muse, mutect2, varscan2
- DCAF4L2 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 19/323 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1388562595, COSV60476670; called by muse, mutect2
- DNAH2 | c.7507C>T p.R2503C | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs139846922, COSV66728594; called by muse, mutect2, varscan2
- GUCY1A2 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as rs369582112; called by muse, mutect2, varscan2
- KCNH8 | c.1847C>A p.A616E | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.9); catalogued as COSV60479962; called by muse, mutect2, varscan2
- RFLNB | c.14T>C p.L5P | Missense Mutation (SNP) | VAF 9/249 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs868962144; called by muse, mutect2
- RTN4R | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 171/350 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.227); catalogued as rs748963344, COSV50384129; called by muse, mutect2, varscan2
- WNK2 | c.5476C>T p.R1826W (on ENST00000297954 / NM_001282394.1; = p.R1789W on NM_006648.3) | Missense Mutation (SNP) | VAF 214/497 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs768001319, COSV99941040; called by muse, mutect2
- ASXL1 | c.156_157insTGGGCAGAGGTA p.P52_L53insWAEV | In Frame Ins (INS) | VAF 41/122 reads (34%) | called by mutect2, pindel*, varscan2
- ATP6V0A4 | c.2104G>T p.D702Y | Missense Mutation (SNP) | VAF 87/219 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- CPAMD8 | c.292_293insC p.V98Afs*5 (on ENST00000651564; = p.V51Afs*5 on NM_015692.5) | Frame Shift Ins (INS) | VAF 103/230 reads (45%) | called by mutect2, pindel*, varscan2
- ELL3 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 9/215 reads (4%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.992); called by muse, mutect2
- SOGA3 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 229/448 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- STAT2 | c.2516_2525delinsT p.H839_T842delinsL | In Frame Del (DEL) | VAF 88/269 reads (33%) | called by pindel, varscan2*
- ZNF99 | c.2281T>A p.C761S | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MYO16 | c.1962C>T p.F654= | Silent (SNP) | VAF 71/162 reads (44%) | catalogued as rs768368069; called by muse, mutect2, varscan2
